Gene-level copy-number profile of tumor specimen TCGA-TT-A6YK-01A from TCGA case TCGA-TT-A6YK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 61.6 years (22,500 days).
Specimen TCGA-TT-A6YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.f1d9a741-ea9b-4292-a835-d5e5f39897f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TT-A6YK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3fc55ce-0151-4501-97ca-72b8b2d03f5c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,748; copy number 2: 48,072.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TT-A6YK-01A-11D-A35H-01): tumor purity 0.55, ploidy 3.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
